Somatic mutation profile of tumor specimen TCGA-CV-6962-01A (aliquot TCGA-CV-6962-01A-11D-1912-08) from TCGA case TCGA-CV-6962, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 66.0 years (24,103 days).
Specimen TCGA-CV-6962-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4cfdae8b-d181-42f6-bbde-8ba6e90502e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-6962-10A (Blood Derived Normal), aliquot TCGA-CV-6962-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ce12f99-ae6b-45f2-8a52-34617d6d95eb

The open-access MAF lists 157 somatic variants for this specimen: 130 protein-altering or splice-affecting, 22 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 22, Frame Shift Del 11, Nonsense Mutation 10, Frame Shift Ins 4, Splice Site 3, Intron 2, 3'Flank 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 29/51 reads (57%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- CDKN2A | c.329G>A p.W110* | Nonsense Mutation (SNP) | VAF 44/50 reads (88%) | hotspot (GDC flag); catalogued as rs1057519852, COSV58682976, COSV58690849; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CREBBP | c.4349A>G p.Y1450C | Missense Mutation (SNP) | VAF 23/27 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52119179, COSV52130109; called by muse, mutect2, varscan2
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 42/51 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACBD3 | c.1109C>G p.A370G | Missense Mutation (SNP) | VAF 84/230 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV100831019; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1889C>A p.A630D | Missense Mutation (SNP) | VAF 60/75 reads (80%) | SIFT tolerated (0.57); PolyPhen benign (0.039); catalogued as rs200247659, COSV99719145; called by muse, mutect2, varscan2
- ADCY1 | c.592G>T p.V198F | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV99812131; called by muse, mutect2, varscan2
- AFF3 | c.1002G>T p.K334N | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100419131; called by muse, mutect2, varscan2
- ANKK1 | c.722G>C p.G241A | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58274131; called by muse, mutect2
- ANKRD17 | c.4174G>C p.A1392P | Missense Mutation (SNP) | VAF 48/68 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV100429308; called by muse, mutect2, varscan2
- APCDD1L | c.167A>C p.N56T | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100954009; called by muse, varscan2
- APOH | c.127C>G p.P43A | Missense Mutation (SNP) | VAF 84/186 reads (45%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.471); catalogued as COSV99235796; called by muse, mutect2, varscan2
- ARID3A | c.1660G>C p.G554R | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV99708381; called by muse, mutect2, varscan2
- ARMC4 | c.902A>G p.K301R | Missense Mutation (SNP) | VAF 42/51 reads (82%) | SIFT tolerated (0.41); PolyPhen benign (0.037); catalogued as COSV99518655; called by muse, mutect2, varscan2
- ARMCX5 | c.570A>T p.E190D | Missense Mutation (SNP) | VAF 81/94 reads (86%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); catalogued as rs935033680, COSV99863414; called by muse, mutect2, varscan2
- ASNS | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs138299423; called by muse, mutect2, varscan2
- ATP2A3 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99989253; called by muse, mutect2
- CABS1 | c.1136A>T p.E379V | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV99909087; called by muse, mutect2, varscan2
- CACNA1G | c.5929C>A p.P1977T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV100661907; called by muse, mutect2, varscan2
- CBLB | c.206A>G p.N69S | Missense Mutation (SNP) | VAF 59/65 reads (91%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV99913558; called by muse, mutect2, varscan2
- CCDC89 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs1415675372, COSV57035203; called by muse, mutect2, varscan2
- CFAP61 | c.1655G>A p.R552H | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.695); catalogued as rs770238633, COSV55634258; called by muse, mutect2, varscan2
- COL1A2 | c.779C>A p.A260D | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.617); catalogued as COSV99799919; called by muse, mutect2, varscan2
- COQ8B | c.1015A>C p.S339R | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as COSV99699450; called by muse, mutect2
- CTC1 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0.26); catalogued as COSV100236484; called by muse, mutect2, varscan2
- DCAF4 | c.92+1G>A p.X31_splice | Splice Site (SNP) | VAF 73/109 reads (67%) | catalogued as COSV100611050; called by muse, mutect2, varscan2
- DOCK6 | c.4396C>T p.L1466F | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs755570842, COSV99625719; called by muse, mutect2, varscan2
- EBF3 | c.1276G>T p.G426C (on ENST00000355311 / NM_001375392.1; = p.G417C on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/118 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.469); catalogued as COSV100799270; called by muse, mutect2, varscan2
- EP400 | c.3142C>T p.P1048S | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57762632; called by muse, mutect2, varscan2
- EPHB6 | c.2885G>T p.G962V | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100844329; called by muse, mutect2, varscan2
- ESPL1 | c.171C>A p.C57* | Nonsense Mutation (SNP) | VAF 42/76 reads (55%) | catalogued as COSV99229391; called by muse, mutect2, varscan2
- FAM102B | c.557-1G>C p.X186_splice | Splice Site (SNP) | VAF 26/37 reads (70%) | catalogued as COSV100899288; called by muse, mutect2, varscan2
- FLNC | c.4697C>G p.A1566G | Missense Mutation (SNP) | VAF 49/201 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100368186; called by muse, mutect2, varscan2
- FOXR2 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 56/64 reads (88%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.712); catalogued as COSV100189513; called by muse, mutect2, varscan2
- GIMAP6 | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 18/110 reads (16%) | catalogued as COSV100188259; called by muse, mutect2, varscan2
- GIT2 | c.211G>A p.G71S | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs765883365, COSV100189062; called by muse, mutect2, varscan2
- GRN | c.1292C>T p.A431V | Missense Mutation (SNP) | VAF 60/122 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV50009133; called by muse, mutect2, varscan2
- H2AC8 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.812); catalogued as rs758481205, COSV99773257; called by muse, mutect2, varscan2
- HDAC9 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs763335887, COSV67773992; called by muse, mutect2, varscan2
- HDGFL2 | c.1421A>G p.K474R | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV100012257; called by muse, mutect2, varscan2
- HECW1 | c.2791+1G>A p.X931_splice | Splice Site (SNP) | VAF 66/158 reads (42%) | catalogued as COSV101223725; called by muse, mutect2, varscan2
- HSPA6 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs774167328, COSV100554173; called by muse, mutect2, varscan2
- HYAL4 | c.35G>A p.C12Y | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99772268; called by muse, mutect2, varscan2
- IGSF11 | c.768T>A p.F256L (on ENST00000393775 / NM_001015887.3; = p.F255L on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/246 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100677429; called by muse, mutect2, varscan2
- ISLR2 | c.515C>A p.A172E | Missense Mutation (SNP) | VAF 82/93 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100679605, COSV100679631; called by muse, mutect2, varscan2
- ITGB1 | c.2106T>G p.Y702* | Nonsense Mutation (SNP) | VAF 18/27 reads (67%) | catalogued as COSV100171711; called by muse, mutect2, varscan2
- JAK1 | c.3141G>A p.W1047* | Nonsense Mutation (SNP) | VAF 17/23 reads (74%) | catalogued as COSV53807887; called by muse, mutect2, varscan2
- KANSL1 | c.611del p.G204Vfs*2 | Frame Shift Del (DEL) | VAF 42/286 reads (15%) | catalogued as rs1304078301; called by mutect2, pindel, varscan2
- KCNV1 | c.1203C>A p.D401E | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.8); PolyPhen benign (0.381); catalogued as COSV99819149, COSV99819477; called by muse, mutect2, varscan2
- KIAA1958 | c.1229A>G p.D410G | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100516146; called by muse, mutect2, varscan2
- KIF13A | c.4763G>T p.R1588L | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.83); catalogued as COSV99436244; called by muse, mutect2, varscan2
- KIF21B | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs752592969, COSV59763902; called by muse, mutect2, varscan2
- KLF14 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs782497758, COSV99081944; called by muse, mutect2, varscan2
- KRT32 | c.1319G>T p.C440F | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV99863047; called by muse, mutect2, varscan2
- KSR1 | c.154A>T p.I52F | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs750526779, COSV60284734; called by muse, mutect2, varscan2
- LIG4 | c.1645A>T p.I549F | Missense Mutation (SNP) | VAF 36/50 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63598114; called by muse, mutect2, varscan2
- LRP1B | c.6941T>A p.M2314K | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV101257719; called by muse, mutect2, varscan2
- LTBP1 | c.2188C>A p.P730T (on ENST00000404816 / NM_206943.4; = p.P404T on NM_000627.4) | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100617269; called by muse, mutect2, varscan2
- MEN1 | c.355A>T p.K119* | Nonsense Mutation (SNP) | VAF 55/102 reads (54%) | catalogued as CM077600, COSV100198239; called by muse, mutect2, varscan2
- MUC17 | c.10057G>A p.V3353I | Missense Mutation (SNP) | VAF 476/865 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as COSV100073605; called by muse, mutect2, varscan2
- MYO1C | c.307C>T p.R103C (on ENST00000648651 / NM_001080779.2; = p.R68C on NM_033375.5) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as rs910022942, COSV100704380; called by muse, mutect2, varscan2
- NCAM2 | c.2258T>A p.L753H | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV99523317; called by muse, mutect2, varscan2
- NELL2 | c.1888T>A p.C630S | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV100419800; called by muse, mutect2, varscan2
- NEURL2 | c.343A>G p.I115V | Missense Mutation (SNP) | VAF 51/61 reads (84%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.672); catalogued as COSV99509904; called by muse, mutect2, varscan2
- NLRP6 | c.2386G>A p.D796N | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs376822405; called by muse, mutect2, varscan2
- NOTCH1 | c.1286G>A p.C429Y | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53051339, COSV53074477; called by muse, mutect2, varscan2
- NRAP | c.2270A>T p.Q757L (on ENST00000359988 / NM_001322945.2; = p.Q722L on NM_006175.4) | Missense Mutation (SNP) | VAF 41/57 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as COSV100748458; called by muse, mutect2, varscan2
- NRCAM | c.1927G>A p.V643I | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs762906676, COSV61033617; called by muse, mutect2, varscan2
- OR2L2 | c.933A>C p.K311N | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV100823783; called by muse, mutect2
- OR4D6 | c.331G>T p.D111Y | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100271718; called by muse, mutect2, varscan2
- OR51A4 | c.666C>G p.I222M | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100985266; called by muse, mutect2, varscan2
- OR5H15 | c.542C>A p.T181N | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV100736678, COSV62947379; called by muse, varscan2
- OR8B4 | c.312T>G p.C104W | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV100635824; called by muse, mutect2, varscan2
- OR8J3 | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs768740274, COSV100040865, COSV56880753; called by muse, mutect2, varscan2
- PALB2 | c.1466C>T p.S489F | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV99848583; called by muse, mutect2, varscan2
- PCDHGA4 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 55/78 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs375047889; called by muse, mutect2, varscan2
- PCF11 | c.3625C>A p.P1209T | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV100018510; called by muse, mutect2, varscan2
- PIK3C2A | c.3191G>A p.R1064K | Missense Mutation (SNP) | VAF 55/69 reads (80%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV99790812; called by muse, mutect2, varscan2
- PKP4 | c.2532A>T p.E844D | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100733859; called by muse, mutect2, varscan2
- PLD1 | c.892C>T p.R298* | Nonsense Mutation (SNP) | VAF 92/103 reads (89%) | catalogued as rs373694099; called by muse, mutect2, varscan2
- PLEKHM2 | c.2569A>G p.S857G | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as rs1557663715, COSV99606646; called by muse, mutect2, varscan2
- PLXNA2 | c.3968G>A p.R1323Q | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs374038859; called by muse, mutect2, varscan2
- PNPLA8 | c.1067G>A p.R356K | Missense Mutation (SNP) | VAF 163/327 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV99993568; called by muse, mutect2, varscan2
- PON3 | c.368A>G p.D123G | Missense Mutation (SNP) | VAF 89/155 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs1313988264, COSV99672520; called by muse, mutect2, varscan2
- PPP2R5C | c.1527G>C p.L509F | Missense Mutation (SNP) | VAF 66/95 reads (69%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.938); catalogued as COSV100159563; called by muse, mutect2, varscan2
- PRB3 | c.115C>T p.R39* | Nonsense Mutation (SNP) | VAF 120/294 reads (41%) | catalogued as rs533793961, COSV54389356; called by muse, mutect2, varscan2
- PROK1 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); catalogued as rs760109897, COSV99602587; called by muse, mutect2, varscan2
- PRRX1 | c.593C>G p.P198R | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV53416880, COSV53417805, COSV99509573; called by muse, mutect2, varscan2
- RHOBTB2 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 56/76 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs1421307313, COSV99311026; called by muse, mutect2, varscan2
- RIMBP2 | c.2892C>A p.D964E | Missense Mutation (SNP) | VAF 119/364 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99899648; called by muse, mutect2, varscan2
- S1PR4 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.546); catalogued as rs562421570, COSV55740025, COSV55741174; called by muse, mutect2, varscan2
- SERPINE1 | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99776723; called by muse, mutect2, varscan2
- SLC6A4 | c.1637C>G p.P546R | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99911401; called by muse, mutect2, varscan2
- SPATA17 | c.866A>G p.D289G | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV100861165; called by muse, mutect2, varscan2
- SRGAP1 | c.1958A>G p.Y653C | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV61896025; called by muse, mutect2, varscan2
- SRGAP3 | c.1979G>T p.G660V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100840998; called by muse, mutect2, varscan2
- SRPK2 | c.613C>A p.H205N | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100624079; called by muse, mutect2, varscan2
- SRSF2 | c.385C>G p.R129G | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.055); catalogued as COSV100333944, COSV57976044; called by muse, mutect2, varscan2
- STXBP4 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as COSV100178188; called by muse, mutect2, varscan2
- TAF1C | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759412906, COSV100499618; called by muse, mutect2, varscan2
- TECRL | c.107T>C p.L36S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.193); catalogued as COSV101168991; called by muse, mutect2, varscan2
- THEM5 | c.467T>G p.F156C | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs755094159, COSV100917245; called by muse, mutect2, varscan2
- TMEM132E | c.1842C>G p.S614R (on ENST00000321639; = p.S704R on NM_001304438.2) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV100396401; called by muse, mutect2, varscan2
- TNRC6B | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.902); catalogued as COSV57310634; called by muse, mutect2, varscan2
- TRANK1 | c.7637G>T p.R2546L | Missense Mutation (SNP) | VAF 39/49 reads (80%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as rs375887057, COSV100083162; called by muse, mutect2, varscan2
- TTC39C | c.1192C>T p.Q398* (on ENST00000317571 / NM_001135993.2; = p.Q337* on NM_153211.4) | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as COSV100455439; called by muse, mutect2, varscan2
- TTN | c.24515G>T p.W8172L (on ENST00000591111; = p.W7245L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/75 reads (47%) | PolyPhen probably damaging (0.999); catalogued as COSV100615941; called by muse, mutect2, varscan2
- USP16 | c.1851C>A p.F617L | Missense Mutation (SNP) | VAF 70/84 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV100537963; called by muse, mutect2, varscan2
- WNT11 | c.194T>C p.L65P | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100490349; called by muse, mutect2, varscan2
- ZBTB14 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.972); catalogued as COSV100813463; called by muse, mutect2, varscan2
- ZNF157 | c.459A>C p.K153N | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100998503; called by muse, mutect2, varscan2
- ZNF347 | c.1628G>A p.C543Y | Missense Mutation (SNP) | VAF 62/117 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV100498311; called by muse, mutect2, varscan2
- ZNF440 | c.1150C>T p.R384* | Nonsense Mutation (SNP) | VAF 27/51 reads (53%) | catalogued as rs780215713, COSV58370732; called by muse, mutect2, varscan2
- ZNF492 | c.128del p.P43Qfs*24 | Frame Shift Del (DEL) | VAF 60/112 reads (54%) | catalogued as rs1357604127; called by mutect2, varscan2
- ZNF687 | c.922G>T p.G308W | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99649828; called by muse, mutect2, varscan2
- ZNF687 | c.923G>T p.G308V | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as COSV99649829; called by muse, mutect2, varscan2
- ABHD3 | c.782_789del p.P261Lfs*5 | Frame Shift Del (DEL) | VAF 30/120 reads (25%) | called by mutect2, pindel, varscan2
- ADCYAP1 | c.374_375del p.A125Gfs*38 | Frame Shift Del (DEL) | VAF 68/188 reads (36%) | called by pindel, varscan2
- COQ8A | c.457_470del p.F153Lfs*22 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | called by mutect2, pindel, varscan2
- DOCK2 | c.3962dup p.N1321Kfs*10 | Frame Shift Ins (INS) | VAF 16/75 reads (21%) | called by mutect2, pindel, varscan2
- GGNBP2 | c.192G>C p.K64N | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LAT | c.583del p.E195Sfs*7 | Frame Shift Del (DEL) | VAF 33/93 reads (35%) | called by mutect2, pindel, varscan2
- LILRB3 | c.84dup p.P29Tfs*6 | Frame Shift Ins (INS) | VAF 21/59 reads (36%) | called by mutect2, varscan2
- NAP1L1 | c.278_305del p.A93Vfs*45 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | called by mutect2, pindel
- NUP133 | c.1160del p.T387Mfs*2 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- RALGAPA1 | c.1471G>A p.D491N | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- SCAMP1 | c.464del p.L155Cfs*7 | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | called by mutect2, varscan2
- SCNN1B | c.1790del p.R597Pfs*79 | Frame Shift Del (DEL) | VAF 20/61 reads (33%) | called by mutect2, pindel, varscan2
- ZFP36L2 | c.398dup p.H133Qfs*341 | Frame Shift Ins (INS) | VAF 13/38 reads (34%) | called by mutect2, pindel, varscan2
- ZNF404 | c.485_507del p.N162Sfs*7 | Frame Shift Del (DEL) | VAF 46/93 reads (49%) | called by mutect2, pindel, varscan2
- ADAMTS19 | c.69C>T p.F23= | Silent (SNP) | VAF 59/80 reads (74%) | catalogued as COSV99179016; called by muse, mutect2, varscan2
- ADCY10 | c.708C>T p.F236= | Silent (SNP) | VAF 62/364 reads (17%) | catalogued as COSV100896895; called by muse, mutect2, varscan2
- C17orf75 | c.171C>T p.D57= | Silent (SNP) | VAF 103/270 reads (38%) | catalogued as rs377619237; called by muse, varscan2
- CD300E | c.57G>A p.K19= | Silent (SNP) | VAF 26/46 reads (57%) | catalogued as rs747167998, COSV100151316; called by muse, mutect2, varscan2
- CFAP47 | c.648A>G p.E216= | Silent (SNP) | VAF 42/51 reads (82%) | catalogued as COSV99935153; called by muse, mutect2, varscan2
- DGKG | c.1089G>A p.A363= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as rs760898865, COSV99403476; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.936A>G p.K312= | Silent (SNP) | VAF 51/87 reads (59%) | catalogued as rs778040848, COSV99143670; called by muse, mutect2, varscan2
- OR4C6 | c.129T>C p.I43= | Silent (SNP) | VAF 90/160 reads (56%) | catalogued as COSV100051660; called by muse, mutect2, varscan2
- OR8I2 | c.714C>A p.S238= | Silent (SNP) | VAF 66/137 reads (48%) | catalogued as COSV56168822; called by muse, mutect2, varscan2
- OSBPL3 | c.1677C>T p.L559= | Silent (SNP) | VAF 48/124 reads (39%) | catalogued as COSV100514181; called by muse, mutect2, varscan2
- PADI4 | c.921G>A p.E307= | Silent (SNP) | VAF 17/24 reads (71%) | catalogued as COSV100966841; called by muse, mutect2, varscan2
- RBP3 | c.2664C>A p.P888= | Silent (SNP) | VAF 19/33 reads (58%) | called by muse, mutect2, varscan2
- RETREG3 | c.1224G>T p.L408= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as COSV99518967; called by muse, mutect2, varscan2
- RINL | c.768G>A p.E256= (on ENST00000591812 / NM_001195833.2; = p.E142= on NM_198445.4) | Silent (SNP) | VAF 30/120 reads (25%) | catalogued as COSV100531188; called by muse, mutect2, varscan2
- RYR1 | c.10275G>A p.T3425= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as rs769992246, COSV62113838; ClinVar: likely benign; called by muse, mutect2, varscan2
- SH3GL1 | c.202C>T p.L68= | Silent (SNP) | VAF 45/95 reads (47%) | catalogued as COSV99522595; called by muse, mutect2, varscan2
- SPANXD | c.219A>G p.R73= | Silent (SNP) | VAF 195/249 reads (78%) | catalogued as COSV100982284; called by muse, mutect2, varscan2
- TMEM147 | c.357A>G p.L119= | Silent (SNP) | VAF 59/120 reads (49%) | catalogued as rs35486099; called by muse, mutect2, varscan2
- TNRC18 | c.5427G>A p.A1809= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as rs753845626, COSV101269695; called by muse, mutect2, varscan2
- TRHR | c.111C>A p.G37= | Silent (SNP) | VAF 39/95 reads (41%) | catalogued as COSV100304875; called by muse, mutect2, varscan2
- UBE2M | c.225G>A p.K75= | Silent (SNP) | VAF 27/39 reads (69%) | catalogued as rs1441039980, COSV99448181; called by muse, mutect2, varscan2
- ZNF85 | c.855C>A p.P285= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV100059855; called by mutect2, varscan2
- AL353804.7 | chrX:73851475 C>T | 3'Flank (SNP) | VAF 130/158 reads (82%) | called by muse, mutect2, varscan2
- ANK3 | c.12596-402C>A | Intron (SNP) | VAF 51/71 reads (72%) | catalogued as COSV99780284; called by muse, mutect2, varscan2
- LOXL2 | c.-83-17575T>A | Intron (SNP) | VAF 45/63 reads (71%) | catalogued as COSV100652664; called by muse, mutect2, varscan2
- MIR519A2 | n.29C>T | RNA (SNP) | VAF 73/138 reads (53%) | catalogued as rs142071806; called by muse, mutect2, varscan2
- TMPO | chr12:98537539 A>T | 3'Flank (SNP) | VAF 7/21 reads (33%) | catalogued as COSV99702041; called by muse, mutect2, varscan2
